HCMI case HCM-BROD-0555-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0cd60ea0-92de-44fa-86be-c75842b4123e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1970; Vital status: Dead; Days to death: 25 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 48.2 years (17,601 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIB; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: Yes; Sites of involvement: Liver.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 4 days; Days to treatment end: 14 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 25 days.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.2; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 48.2 years (17,601 days); Gastric esophageal junction involvement: No.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Follow-up contact recording only the day: day 25.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0555-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0555-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
